PECGS case C083-000038 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/df0b2e0e-0910-4c9a-a9a9-ec01e9e9cffe

Demographics
Sex at birth: female; Age at index: 51 years; Year of birth: 1971; Education level: Vocational College or Some College.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Cecum; Age at diagnosis: 50.8 years (18,555 days); AJCC pathologic stage: Stage IIIC; Progression or recurrence: yes.

Other clinical attributes
- Menopause status: Postmenopausal.

Biospecimens (2 samples)
- Sample C083-000038_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000038_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
